CCDI case PBCDHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ac81200f-15ae-492c-8825-b322a2b92ee7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.9 years (6,163 days).

Biospecimens (3 samples)
- Sample 0DPE94: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPE9D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPE9X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
